Somatic mutation profile of tumor specimen TARGET-30-PARMLF-01A (aliquot TARGET-30-PARMLF-01A-01D) from TARGET case TARGET-30-PARMLF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 6.9 years (2,512 days).
Specimen TARGET-30-PARMLF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 477608a4-685a-475a-855f-d191ac6d47e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARMLF-10A (Blood Derived Normal), aliquot TARGET-30-PARMLF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/501f364c-bfce-4a8b-8d32-e46a9ad9f9f8

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 24, Silent 8, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A1 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1443081862, COSV100618168, COSV62201359; called by muse, mutect2
- COL11A2 | c.4537C>T p.R1513W (on ENST00000341947 / NM_080680.3; = p.R1406W on NM_080679.2) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs199615717, COSV59503664; called by muse, mutect2, varscan2
- COL3A1 | c.3370G>T p.A1124S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58598081; called by muse, mutect2, varscan2
- DMBT1 | c.7204C>G p.P2402A (on ENST00000338354 / NM_001377530.1; = p.P1645A on NM_004406.3) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57566928; called by muse, mutect2, varscan2
- FAM47A | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60499203, COSV60500380; called by muse, mutect2
- FAM71F1 | c.494A>C p.Q165P | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV59375142; called by muse, mutect2, varscan2
- FCGR3B | c.409C>G p.H137D | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.408); catalogued as COSV54212623; called by muse, mutect2, varscan2
- MMP2 | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.391); catalogued as COSV54606088; called by muse, mutect2, varscan2
- MUC16 | c.22580C>A p.S7527Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV67442524, COSV67459123; called by muse, mutect2, varscan2
- MUC4 | c.15764C>T p.A5255V (on ENST00000463781 / NM_018406.7; = p.A1019V on NM_004532.6) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs137940766, COSV57806572; called by muse, mutect2, varscan2
- MYLK | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60609652; called by muse, mutect2
- PLA2G4A | c.2086C>A p.L696I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66557683; called by muse, mutect2, varscan2
- PLEKHS1 | c.979C>T p.P327S (on ENST00000369310 / NM_182601.1; = p.P347S on NM_024889.5) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.359); catalogued as COSV63057154; called by muse, mutect2, varscan2
- PRRC1 | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV56992626; called by muse, mutect2
- RBMXL1 | c.656G>C p.S219T | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV53106553; called by muse, mutect2, varscan2
- RIPOR1 | c.2002C>T p.P668S (on ENST00000379312 / NM_001193522.2; = p.P664S on NM_024519.4) | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1159218687, COSV50285769; called by muse, mutect2, varscan2
- SLC12A6 | c.135T>G p.F45L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV62548468; called by muse, mutect2, varscan2
- UNC13C | c.2681G>C p.S894T | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as rs200592386; called by muse, mutect2, varscan2
- WDR3 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV60470244; called by muse, mutect2, varscan2
- ZNF496 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749333180; called by muse, mutect2, varscan2
- ZNF552 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV66971847, COSV66971857, COSV66972004; called by muse, mutect2, varscan2
- CSMD1 | c.3553A>G p.N1185D (on ENST00000520002; = p.N1184D on NM_033225.6) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- KLHL25 | c.1552_1555dup p.T519Mfs*36 | Frame Shift Ins (INS) | VAF 10/90 reads (11%) | called by mutect2, pindel
- PBRM1 | c.1088-8_1089del p.X363_splice | Splice Site (DEL) | VAF 12/22 reads (55%) | called by mutect2, pindel
- UGT2A2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZSWIM3 | c.151A>T p.I51F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- AMZ2 | c.720A>C p.I240= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV63083830; called by muse, mutect2, varscan2
- CNTNAP5 | c.1362C>T p.S454= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV70516893; called by muse, mutect2, varscan2
- CST4 | c.211C>T p.L71= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1412079867, COSV54150659; called by muse, mutect2, varscan2
- FLT4 | c.3978C>A p.A1326= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV56125036; called by muse, mutect2, varscan2
- LONRF1 | c.2121T>C p.L707= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV68038163; called by muse, mutect2, varscan2
- PARD3 | c.882A>G p.R294= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as COSV60764768; called by muse, mutect2, varscan2
- SFTPD | c.465G>A p.S155= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs774573151, COSV64853860; called by muse, mutect2, varscan2
- ZSWIM3 | c.150C>T p.D50= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
